Somatic mutation profile of tumor specimen TCGA-BG-A0M6-01A (aliquot TCGA-BG-A0M6-01A-31D-A10B-09) from TCGA case TCGA-BG-A0M6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 73.0 years (26,666 days).
Specimen TCGA-BG-A0M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed3bc919-b55d-4460-b113-353097317afa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M6-10A (Blood Derived Normal), aliquot TCGA-BG-A0M6-10A-01W-A10C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/579feb01-28fe-4cb5-8873-ecf160dbdd2d

The open-access MAF lists 46 somatic variants for this specimen: 39 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 32, Silent 7, Frame Shift Ins 2, Splice Region 2, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>C p.E1813A | Missense Mutation (SNP) | VAF 53/95 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- PIK3CA | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs121913275, COSV55874040, COSV55875881, COSV55956933; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 39/48 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.10736C>A p.T3579K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101446695, COSV71283618; called by muse, mutect2, varscan2
- ADARB2 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as rs367615505; called by muse, mutect2, varscan2
- ARFGEF2 | c.2440T>A p.Y814N | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64210632; called by muse, mutect2, varscan2
- ARHGAP29 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53108597, COSV99557758; called by muse, mutect2, varscan2
- ATG2B | c.5857G>A p.A1953T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV55889453; called by muse, mutect2, varscan2
- ATL3 | c.1282T>C p.F428L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs777811140, COSV60295276; called by muse, mutect2, varscan2
- CC2D2A | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV67502334; called by muse, mutect2, varscan2
- DMAP1 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 79/148 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV60000007; called by muse, mutect2, varscan2
- FAM76A | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as COSV50548771; called by muse, mutect2
- FMR1 | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.52); catalogued as CM1414787, COSV54421956; called by muse, mutect2, varscan2
- GRAMD1C | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as COSV63981900; called by muse, mutect2, varscan2
- LRP6 | c.3811G>C p.D1271H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53783657; called by muse, mutect2, varscan2
- MICAL2 | c.864C>A p.N288K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56316763; called by muse, mutect2, varscan2
- MSH6 | c.2830A>G p.I944V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as rs878853723, COSV52274780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTIF2 | c.1422T>G p.H474Q | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV55050288; called by muse, mutect2, varscan2
- NFASC | c.1507G>A p.A503T (on ENST00000339876 / NM_001378329.1; = p.A514T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs780692017, COSV58359304; called by muse, mutect2, varscan2
- NOC3L | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64929626; called by muse, mutect2
- OTUD6B | c.348A>C p.E116D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53442050; called by muse, mutect2
- PTPN3 | c.461T>A p.V154E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52702188, COSV99356487; called by muse, mutect2, varscan2
- RIC1 | c.1903C>G p.R635G | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.695); catalogued as COSV52604297, COSV52605234, COSV52614879; called by muse, mutect2
- SARS2 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55498346; called by muse, mutect2, varscan2
- SLC2A14 | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV61585617; called by muse, mutect2, varscan2
- SLCO1C1 | c.1185C>T p.I395= | Splice Region (SNP) | VAF 64/109 reads (59%) | catalogued as rs766093648, COSV56868647; called by muse, mutect2, varscan2
- STAG2 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV54351358, COSV54366193; called by muse, mutect2, varscan2
- STARD8 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767763715, COSV52922074; called by muse, mutect2, varscan2
- STPG4 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV54277812; called by muse, mutect2, varscan2
- TLK1 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1268184608, COSV62629038; called by muse, mutect2, varscan2
- TM7SF3 | c.160A>C p.I54L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV58001415; called by muse, mutect2, varscan2
- TTC6 | c.360T>G p.T120= (on ENST00000267368; = p.T1486= on NM_001310135.3) | Splice Region (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99941636; called by muse, mutect2
- UBASH3B | c.723C>G p.D241E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.358); catalogued as COSV52490590; called by muse, mutect2
- AL645922.1 | c.2816_2819dup p.I941Efs*12 | Frame Shift Ins (INS) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- NF1 | c.7632dup p.D2545* (on ENST00000358273 / NM_001042492.3; = p.D2524* on NM_000267.3) | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- PLXNB3 | c.1648del p.R550Gfs*55 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | called by mutect2, varscan2
- PRAMEF19 | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TNIP3 | c.41_43dup p.A14dup | In Frame Ins (INS) | VAF 6/67 reads (9%) | called by mutect2, pindel
- AGRP | c.243C>T p.P81= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV52096836; called by muse, mutect2, varscan2
- EXOC1 | c.1872A>G p.Q624= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV62119190; called by muse, mutect2, varscan2
- MBL2 | c.417C>T p.F139= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs267602524, COSV64758019; called by muse, mutect2
- SCN4A | c.4263C>T p.F1421= | Silent (SNP) | VAF 62/122 reads (51%) | catalogued as rs267604989, COSV71125679; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINB6 | c.594G>A p.K198= (on ENST00000612421 / NM_001271823.2; = p.K179= on NM_004568.6) | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV59564925; called by muse, varscan2
- SLC12A5 | c.408C>T p.G136= (on ENST00000454036 / NM_001134771.2; = p.G113= on NM_020708.5) | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as rs145327140; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP37 | c.699A>C p.T233= | Silent (SNP) | VAF 58/216 reads (27%) | catalogued as rs1246374633, COSV51441472, COSV51444319; called by muse, mutect2, varscan2
